CCDI case PBCBGA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/f9641da2-f50a-4376-8aa9-016c53bdae98

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 3.9 years (1,430 days).

Biospecimens (3 samples)
- Sample 0DNGG7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNGGK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNGGR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
